Surgical pathology report (de-identified scan), TCGA case TCGA-24-1557, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1557-01A (Primary Tumor).

[page 1 of 4]
Physician(s):

Other Related Clinical Data:

DIAGNOSIS: OVARIES, LEFT AND RIGHT, OOPHORECTOMY

- BILATERAL POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA
- SEE COMMENT

FALLOPIAN TUBES, LEFT AND RIGHT, SALPINGECTOMY

- BILATERAL METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA IN PERITUBAL SOFT TISSUE

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- INACTIVE ENDOMETRIUM

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA (SEE COMMENT)
- ADENOMYOSIS

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY

- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

SOFT TISSUE, LABELED "TUMOR TISSUE," EXCISION

- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

OMENTUM, RESECTION

- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

[page 2 of 4]
[REDACTED]

[REDACTED] By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out [REDACTED]

Intraoperative Consultation: Called to OR #23 to pick up "right and left tubes and ovaries--both specimens are received in the same container, measuring 386 grams combined. One is 12 x 7 x 4 cm and the other 8 x 8 x 4 cm. [REDACTED]

Microscopic Description and Comment: Histologic sections of the right and left ovaries show extensive poorly differentiated serous adenocarcinoma. The tumor diffusely involves the omentum, and is also present on the serosal surface of the uterus with focal invasion into the underlying myometrium. [REDACTED]

History: The patient is a [REDACTED] with a pelvic mass. Operative procedure: [REDACTED] laparotomy, omentectomy, TAH/BSO, and radical tumor debulking.

Specimen(s) Received:

- A: OMENTUM
- B: HYSTERECTOMY, LEFT AND RIGHT TUBE AND OVARY
- C: HYSTERECTOMY, UTERUS AND CERVIX
- D: TUMOR TISSUE

Gross Description The specimens are received fresh in four containers, each labelled with the patient's name. The first is labelled "omentum." It consists of a fragment of yellow, firm, soft tissue with admixed adipose tissue measuring 24 x 11 x 1.0 cm. Over 90% of the adipose tissue is involved by coalesced white-dense nodular masses. Labelled A1, A2, omentum, representative sections. Jar 2.

The second container is labelled "right and left tubes and ovaries." It consists of two ovaries with attached fallopian tubes. The first ovary weighs 192 grams and measures 8 x 7 x 6.5 cm, and is completely effaced by multiple, yellow, dense exophytic masses. The attached fallopian tube measures 8.0 cm in length and 1.1 cm in diameter with attached fimbriae and is grossly involved by tumor present in the paratubal soft tissue and in the fallopian tube proper. The second ovary weighs 147 grams, and measures 8 x 6.5 x 5.0 cm, and is completely effaced by multiple, tan, dense tumor nodules. The tumor involves both the ovarian parenchyma as well as the ovarian surface. The attached fallopian tube measures 1.5 cm in length x 0.6 cm in diameter and appears grossly involved by tumor present in the paratubal soft tissue. Multiple dilated cystic spaces ranging from 0.5 to 2.5 cm in diameter are present in both ovaries. Labelled B1 to B3, first ovary and fallopian tube, representative sections; B4-B6, second ovary and fallopian tube, representative sections. [REDACTED]

The third container is labelled "uterus and cervix." It consists of a 186 gram total abdominal hysterectomy specimen including uterus and cervix measuring 10 x 6.0 x 4.0 cm in overall dimension. The anterior and lateral serosal surfaces of the uterus contain multiple, firm, irregular exophytic nodules, ranging from 0.6 to 4.5 cm in maximum dimension. A large, firm pedunculated tumor mass measuring 3.0 x 2.5 x 0.7 cm in present on the lateral serosal surface of the uterus. The endometrial cavity measures 0.8 cm from cornu to cornu and 4.0 cm from fundus to endocervix. The endometrium measures 0.1 cm in average thickness and has a pink smooth mucosal with no lesions grossly identified. The myometrium is 2.2 cm in average thickness and appears grossly unremarkable. The endocervical canal measures 3.2 cm in length and has a tan mucosa with no masses or lesions grossly identified. The exo-cervix measures 4.0 x 3.0 cm with a 0.6 cm ovoid external os. The cervical mucosa is [REDACTED]

[page 3 of 4]
[REDACTED]

tan, smooth, and glistening with focal areas of petechial hemorrhage and no lesions or masses are identified. Labelled C1, anterior endometrium, full thickness; C2, anterior cervix, full thickness; C3-C5, anterior uterine serosa with tumor, representative sections; C6, posterior endometrium, full thickness; C7, posterior cervix; C8 thru C10, posterior uterine serosa and tumor, representative sections. [REDACTED]

The fourth container is labelled "tumor tissue." It consists of three fragments of white, dense, soft tissue mass, measuring 5.0 x 4.0 x 1.2 cm in aggregate. Labelled D1, D2, tumor tissue, representative sections. [REDACTED]

[REDACTED]

Synopsis SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS 1. A neoplasm is PRESENT

2. The HISTOLOGIC DIAGNOSIS is: Serous adenocarcinoma
3. The LOCATION OF THE PRIMARY TUMOR is: Right and left ovary (synchronous primary tumors)
4. The FIGO GRADE of the tumor is: III (Tumor composed of >50% solid cellular nests)
5. The NUCLEAR (BRODERS') GRADE of the tumor is: G3 (Poorly-differentiated)
6. and 7. Tumor IS identified on the ovarian surfaces.
8. Tumor DOES invade the adjacent peritubal soft tissue.
9. Tumor invasion of pelvic soft tissue CANNOT BE EVALUATED.
10. Tumor involvement of the pelvic peritoneum CANNOT BE EVALUATED.
11. Metastatic involvement of the EXTRAPELVIC peritoneum CANNOT BE EVALUATED.
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true pelvis is greater than 10 cm.
14. Metastatic involvement of the uterine serosa is PRESENT.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases CANNOT BE EVALUATED.
17. and 18. The total number of regional lymph nodes examined is: Zero (0).
19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition	Macroscopic
	T3C	IIIC	
peritoneal metastases beyond true pelvis measuring >2 cm in greatest dimension			
THE REGIONAL LYMPH NODES are classified as: NX (Nodal status cannot be assessed)			

THE STATUS OF DISTANT TUMOR SITES is classified as: MX (Status cannot be assessed)

[page 4 of 4]
20. The FINAL AJCC/UICC/FIGO STAGE IS: AJCC/UICC/FIGO

IIIC (T3C/NX/MX)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 86e961bc-2292-4a45-a8f8-0f9bbd092020 (TCGA-24-1557.EC04339C-F1AE-4519-BDDF-E60CC1F30D52.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).